Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6924, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6924-01A (Primary Tumor).

Department of Cancer Pathology

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Multiple organ resection – sigmoid colon**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Sigmoid colon with tumour**

Examination performed on:

Macroscopic description:

A 18.3 cm length of the large intestine with a piece of mesentery sized 19 x 9 x 4 cm. Tumour sized 5.6 x 6.3 x 1.7 found in the mucosa. The lesion surrounds 100% of the intestine circumference, is removed by 9.8 cm from the proximal incision line, and 7.2 cm from the distal incision line.

Microscopic description:

Adenocarcinoma tubulopapillare (G1).

Infiltratio carcinomatosa telae adiposae pericolicae.

Incision lines free of neoplastic lesions.

Lymphonodulitis reactiva (NO VIII).

Histopathological diagnosis:

Adenocarcinoma tubulopapillare coli. Tubulopapillar adenocarcinoma of the colon.

(G1, Dukes B, Astler - Coller B2, pT3, pNO).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 00ae28ec-fe97-47c3-8283-16c828c576b7 (TCGA-D5-6924.6A75E6B8-5ECE-4FB9-9BCA-5A751EAC8D7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).